Somatic mutation profile of tumor specimen TCGA-25-2396-01A (aliquot TCGA-25-2396-01A-01D-0704-01) from TCGA case TCGA-25-2396, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.6 years (26,145 days).
Specimen TCGA-25-2396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed0c0979-d497-4d74-ad24-58b925e895e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2396-10A (Blood Derived Normal), aliquot TCGA-25-2396-10A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f5b4ecf-8f56-4516-9d46-7c622a1bfb62

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 17, Silent 11, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 64/77 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACB | c.5713G>A p.V1905M | Missense Mutation (SNP) | VAF 91/175 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs182648370; called by muse, mutect2, varscan2
- ANKRD26 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); catalogued as rs1169989924, COSV65774032; called by muse, mutect2, varscan2
- AP1G2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756362823, COSV58110195; called by muse, mutect2, varscan2
- ARID4A | c.2605A>G p.I869V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs748437296, COSV62162019, COSV62163928, COSV62166290; called by muse, mutect2, varscan2
- BBS12 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV58561394; called by muse, mutect2, varscan2
- F9 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV54378700, COSV54380932; called by muse, mutect2, varscan2
- FAM214B | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as rs765218132, COSV59715013; called by muse, mutect2, varscan2
- GEN1 | c.2663G>C p.G888A | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58055349; called by muse, mutect2, varscan2
- IWS1 | c.1012_1014del p.K338del | In Frame Del (DEL) | VAF 128/303 reads (42%) | catalogued as COSV54866587; called by mutect2, pindel, varscan2
- JAK3 | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs199706172; called by muse, varscan2
- KCNJ11 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100217591; called by muse, mutect2, varscan2
- MAP3K15 | c.1333A>C p.N445H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.921); catalogued as COSV100135373; called by muse, mutect2
- MYO1C | c.1969G>A p.V657M (on ENST00000648651 / NM_001080779.2; = p.V622M on NM_033375.5) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913679893, COSV100704506; called by muse, mutect2
- NR4A3 | c.989C>A p.A330E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100432836, COSV58243284; called by mutect2, varscan2
- OR5A1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 179/312 reads (57%) | catalogued as rs771050906, COSV57375768; called by muse, mutect2, varscan2
- OR8J1 | c.616A>T p.N206Y | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57316607; called by muse, mutect2, varscan2
- SCN10A | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 44/186 reads (24%) | catalogued as rs763084100, COSV71860285; ClinVar: uncertain significance; called by muse, mutect2
- TONSL | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1392405111, COSV68048513; called by muse, mutect2
- ZNF181 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67626286; called by muse, mutect2, varscan2
- ZNF236 | c.1381dup p.M461Nfs*104 | Frame Shift Ins (INS) | VAF 98/136 reads (72%) | catalogued as rs769237443; called by mutect2, varscan2
- ATP11A | c.1374G>A p.S458= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs778285031, COSV52106272; called by muse, mutect2, varscan2
- CA6 | c.495C>T p.F165= | Silent (SNP) | VAF 80/271 reads (30%) | catalogued as rs1366948886, COSV66261367; called by muse, mutect2, varscan2
- CAPN6 | c.1905C>T p.S635= | Silent (SNP) | VAF 110/237 reads (46%) | catalogued as rs921083346, COSV100137003; called by muse, mutect2, varscan2
- CASK | c.2430C>T p.S810= (on ENST00000378163 / NM_001367721.1; = p.S805= on NM_003688.3) | Silent (SNP) | VAF 71/211 reads (34%) | catalogued as COSV59361717; called by muse, mutect2, varscan2
- CHST15 | c.1522T>C p.L508= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV60560233; called by muse, mutect2, varscan2
- COL12A1 | c.207A>G p.E69= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV59389702; called by muse, mutect2, varscan2
- KCNJ4 | c.594C>T p.G198= | Silent (SNP) | VAF 72/84 reads (86%) | catalogued as COSV57856152; called by muse, mutect2, varscan2
- SERINC2 | c.912C>T p.N304= (on ENST00000373709 / NM_178865.5; = p.N308= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as rs1443147266, COSV101036736, COSV65489351; called by muse, mutect2, varscan2
- STK40 | c.726C>T p.P242= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs763037189, COSV63734705, COSV63735202; called by muse, mutect2
- TKTL2 | c.168G>A p.T56= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs776271739, COSV54917421, COSV99761399; called by muse, mutect2, varscan2
- TRAF3IP2 | c.918G>A p.Q306= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV60675096; called by muse, mutect2, varscan2
